TCGA case TCGA-97-A4LX — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Washington University - NYU. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e2b0d873-4942-4483-9a88-d5c6338d0382

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 81 years; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma with mixed subtypes (the primary disease): ICD-O-3 morphology code: 8255/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Classification of tumor: primary; Age at diagnosis: 81.9 years (29,915 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Prior malignancy: no; Synchronous malignancy: Yes; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Adenocarcinoma with mixed subtypes: ICD-O-3 morphology code: 8255/3; Tissue or organ of origin: Lung, NOS; Laterality: Left; Classification of tumor: Synchronous primary; Age at diagnosis: 81.9 years (29,915 days).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 0 days.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (4 entries)
- Days to follow up: 614 days (1.7 years); Disease response: Tumor Free.
- ECOG performance status: 0; Timepoint: Other.
- ECOG performance status: 1; Timepoint: Preoperative.
- Follow-up contact recording only the day: day 272.

Molecular and laboratory tests
- KRAS substitution: Positive; Amino-acid change: G12A.

Other clinical attributes
- DLCO (% of predicted): 61; FEV1/FVC after bronchodilator (%): 96; FEV1/FVC before bronchodilator (%): 91; FEV1 after bronchodilator (% of reference): 90; FEV1 before bronchodilator (% of reference): 91.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 120; Tobacco smoking onset year: 1945; Tobacco smoking quit year: 1985.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-97-A4LX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 50 mg.
  Slide TCGA-97-A4LX-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
- Sample TCGA-97-A4LX-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-97-A4LX-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma Mixed Subtype; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tobacco smoking history indicator: 3; Anatomic organ subdivision: Lingula; KRAS mutation found: Yes; KRAS gene analysis indicator: Yes; KRAS mutation identified type: G12A; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.
- Other malignancy form: Malignancy type: Synchronous Malignancy; Other malignancy anatomic site: Lung; Other malignancy histological type: Lung Adenocarcinoma Mixed Subtype.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 614 days; disease-specific survival: no event (censored), 614 days; disease-free interval: no event (censored), 614 days; progression-free interval: no event (censored), 614 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-97-A4LX-01A-11D-A24O-01): tumor purity 0.2, ploidy 1.77, whole-genome doublings 0.
